Somatic mutation profile of tumor specimen MMRF_2516_1_BM_CD138pos (aliquot MMRF_2516_1_BM_CD138pos_T1_KHS5U_K15154) from MMRF case MMRF_2516, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 67.9 years (24,805 days).
Specimen MMRF_2516_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 84a631de-2baa-4a51-8a49-8e20d148eab5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2516_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2516_1_PB_Whole_C3_KHS5U_K15153; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fc04c184-948d-4e58-a67c-50c398391d77

The open-access MAF lists 109 somatic variants for this specimen: 44 protein-altering or splice-affecting, 22 silent, 43 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, 3'UTR 28, Silent 22, Intron 8, 5'UTR 3, Splice Site 2, Nonsense Mutation 2, 5'Flank 2, Frame Shift Ins 1, Frame Shift Del 1, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 46/105 reads (44%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- ROS1 | c.4601dup p.N1534Kfs*21 | Frame Shift Ins (INS) | VAF 19/30 reads (63%) | catalogued as rs776274768; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCC11 | c.2642C>T p.S881L | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as rs1567500856; called by muse, mutect2, varscan2
- ADAMTS10 | c.710G>A p.R237Q | Missense Mutation (SNP) | VAF 61/155 reads (39%) | SIFT tolerated (0.35); PolyPhen benign (0.442); catalogued as rs140455325; called by muse, mutect2, varscan2
- ADSL | c.1256G>A p.G419D | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.765); catalogued as COSV53410564; called by muse, mutect2, varscan2
- AXL | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 52/93 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); catalogued as rs776682499, COSV56573005; called by muse, mutect2, varscan2
- FCN1 | c.223C>T p.R75C | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.052); catalogued as rs761901711, COSV65662223; called by muse, mutect2, varscan2
- FIBIN | c.380G>A p.G127E | Missense Mutation (SNP) | VAF 86/293 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.19); catalogued as rs1441121207; called by muse, mutect2, varscan2
- FLT1 | c.2155G>A p.E719K | Missense Mutation (SNP) | VAF 63/127 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.159); catalogued as COSV56717119; called by muse, mutect2, varscan2
- GPHB5 | c.34G>C p.A12P | Missense Mutation (SNP) | VAF 67/137 reads (49%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV58485498; called by muse, mutect2, varscan2
- HOMER2 | c.28C>T p.R10* | Nonsense Mutation (SNP) | VAF 83/324 reads (26%) | catalogued as rs750943670; called by muse, mutect2, varscan2
- IGHJ5 | c.37A>T p.T13S | Missense Mutation (SNP) | VAF 30/40 reads (75%) | PolyPhen benign (0.1); catalogued as rs374682936; called by muse, varscan2
- IGHV2-70 | c.248C>G p.S83C | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs561745237; called by muse, varscan2
- IGLV3-1 | c.171G>C p.K57N | Missense Mutation (SNP) | VAF 50/125 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.5); catalogued as rs191197478; called by muse, varscan2
- KMT2D | c.6578C>T p.P2193L | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.02); catalogued as rs773254679; called by muse, mutect2, varscan2
- LYPLA1 | c.167+1G>A p.X56_splice | Splice Site (SNP) | VAF 7/26 reads (27%) | catalogued as rs1346569181, COSV57604218; called by muse, mutect2, varscan2
- PHIP | c.4901T>G p.L1634R | Missense Mutation (SNP) | VAF 61/63 reads (97%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.451); catalogued as COSV51505328; called by muse, mutect2, varscan2
- PPP1R12C | c.1615G>A p.D539N | Missense Mutation (SNP) | VAF 112/161 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1203135964; called by muse, mutect2, varscan2
- SAPCD2 | c.670G>A p.V224M | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.781); catalogued as rs529515798, COSV104433706; called by muse, mutect2, varscan2
- SI | c.3362C>G p.A1121G | Missense Mutation (SNP) | VAF 75/148 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.15); catalogued as COSV100016723; called by muse, mutect2, varscan2
- TRIM42 | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 49/207 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.033); catalogued as rs1256685492; called by muse, mutect2, varscan2
- UBE2NL | c.8A>C p.E3A | Missense Mutation (SNP) | VAF 59/59 reads (100%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs782362024; called by muse, mutect2, varscan2
- ATP1A4 | c.242C>G p.T81S | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.48); PolyPhen benign (0.014); called by muse, mutect2
- CEMIP | c.1756T>C p.F586L | Missense Mutation (SNP) | VAF 60/187 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CIITA | c.2791C>G p.L931V | Missense Mutation (SNP) | VAF 88/196 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DBR1 | c.1136T>G p.I379S | Missense Mutation (SNP) | VAF 63/140 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.383); called by muse, mutect2, varscan2
- DOCK2 | c.4218C>G p.I1406M | Missense Mutation (SNP) | VAF 52/137 reads (38%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- EPB41L4A | c.888-1G>C p.X296_splice | Splice Site (SNP) | VAF 16/70 reads (23%) | called by muse, mutect2, varscan2
- GHR | c.762G>T p.M254I | Missense Mutation (SNP) | VAF 59/203 reads (29%) | SIFT tolerated (0.93); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- IGHV2-70D | c.287A>C p.K96T | Missense Mutation (SNP) | VAF 47/102 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); called by muse, varscan2
- IGHV2-70D | c.199G>C p.E67Q | Missense Mutation (SNP) | VAF 52/108 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.911); called by muse, varscan2
- IRF1 | c.688G>T p.E230* | Nonsense Mutation (SNP) | VAF 20/44 reads (45%) | called by muse, mutect2, varscan2
- KIF21A | c.691A>C p.T231P | Missense Mutation (SNP) | VAF 12/304 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NETO2 | c.1494C>A p.D498E | Missense Mutation (SNP) | VAF 6/142 reads (4%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.732); called by muse, mutect2
- NOL9 | c.31G>C p.G11R | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- NR1H4 | c.330A>C p.E110D (on ENST00000551379 / NM_001206993.2; = p.E100D on NM_005123.4) | Missense Mutation (SNP) | VAF 51/111 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- NR5A2 | c.357G>T p.R119S (on ENST00000367362 / NM_205860.3; = p.R73S on NM_003822.5) | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0.249); called by muse, mutect2, varscan2
- OR8H2 | c.155T>C p.L52P | Missense Mutation (SNP) | VAF 61/307 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PRUNE1 | c.259G>T p.D87Y | Missense Mutation (SNP) | VAF 91/158 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RNPEP | c.1378T>G p.L460V | Missense Mutation (SNP) | VAF 90/194 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- SFSWAP | c.2356del p.S786Qfs*46 | Frame Shift Del (DEL) | VAF 94/231 reads (41%) | called by mutect2, pindel, varscan2
- TENM3 | c.1074G>A p.M358I | Missense Mutation (SNP) | VAF 55/118 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- ULK1 | c.2684+5G>C | Splice Region (SNP) | VAF 23/40 reads (58%) | called by muse, mutect2, varscan2
- ZNF556 | c.1319T>C p.F440S | Missense Mutation (SNP) | VAF 12/293 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); called by muse, mutect2
- CACNA1C | c.6339T>C p.I2113= (on ENST00000399634 / NM_001167625.1; = p.I2042= on NM_000719.7) | Silent (SNP) | VAF 41/76 reads (54%) | called by muse, mutect2, varscan2
- CAPS2 | c.531G>C p.V177= | Silent (SNP) | VAF 62/184 reads (34%) | called by muse, mutect2, varscan2
- CCDC50 | c.723C>T p.I241= | Silent (SNP) | VAF 73/157 reads (46%) | catalogued as COSV101165340, COSV66667102; called by muse, mutect2, varscan2
- EFL1 | c.591A>G p.Q197= | Silent (SNP) | VAF 75/225 reads (33%) | called by muse, mutect2, varscan2
- FAT3 | c.10983C>T p.F3661= | Silent (SNP) | VAF 87/177 reads (49%) | catalogued as rs771480729, COSV53081477; called by muse, mutect2, varscan2
- FRMPD4 | c.2886C>T p.G962= | Silent (SNP) | VAF 7/101 reads (7%) | catalogued as COSV101042291; called by muse, mutect2
- IGHV2-70D | c.358C>G p.*120= | Silent (SNP) | VAF 26/62 reads (42%) | called by muse, varscan2
- IGHV2-70D | c.186A>T p.P62= | Silent (SNP) | VAF 48/103 reads (47%) | called by muse, varscan2
- IGLV3-1 | c.207T>C p.D69= | Silent (SNP) | VAF 68/122 reads (56%) | catalogued as rs376313046; called by muse, varscan2
- INTS11 | c.282C>T p.H94= | Silent (SNP) | VAF 67/128 reads (52%) | catalogued as rs767166926, COSV60090368; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.2709C>T p.P903= | Silent (SNP) | VAF 50/170 reads (29%) | catalogued as rs745941020, COSV58019837; called by muse, mutect2, varscan2
- LRP2 | c.3495G>T p.S1165= | Silent (SNP) | VAF 128/261 reads (49%) | catalogued as COSV55559865; called by muse, mutect2, varscan2
- MLPH | c.1332C>T p.S444= | Silent (SNP) | VAF 14/37 reads (38%) | called by muse, mutect2, varscan2
- MYOM3 | c.669G>A p.E223= | Silent (SNP) | VAF 43/101 reads (43%) | called by muse, mutect2, varscan2
- PTPN14 | c.1296C>T p.S432= | Silent (SNP) | VAF 52/112 reads (46%) | catalogued as rs979638322, COSV65285320; called by muse, mutect2, varscan2
- RNF214 | c.768G>T p.V256= | Silent (SNP) | VAF 65/228 reads (29%) | called by muse, mutect2, varscan2
- RXFP1 | c.1617T>C p.G539= | Silent (SNP) | VAF 49/91 reads (54%) | called by muse, mutect2, varscan2
- SSTR5 | c.993C>T p.D331= | Silent (SNP) | VAF 54/125 reads (43%) | catalogued as rs750512306, COSV53512717; called by muse, mutect2, varscan2
- STAG1 | c.2157A>G p.L719= | Silent (SNP) | VAF 37/84 reads (44%) | called by muse, mutect2, varscan2
- TBL1XR1 | c.1182T>C p.I394= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as rs973409423; called by muse, mutect2, varscan2
- TGM5 | c.1305C>T p.D435= (on ENST00000220420 / NM_201631.4; = p.D353= on NM_004245.4) | Silent (SNP) | VAF 41/132 reads (31%) | catalogued as rs746187832, COSV55008482; called by muse, mutect2, varscan2
- WDPCP | c.177C>A p.I59= | Silent (SNP) | VAF 7/19 reads (37%) | called by muse, mutect2, varscan2
- ACRBP | c.263-28C>G | Intron (SNP) | VAF 26/76 reads (34%) | called by muse, mutect2, varscan2
- ANAPC16 | c.*344C>A | 3'UTR (SNP) | VAF 4/68 reads (6%) | called by muse, mutect2
- ANKDD1A | c.*1313dup | 3'UTR (INS) | VAF 27/60 reads (45%) | catalogued as rs529369387; called by mutect2, varscan2
- ARL1 | c.*2435C>T | 3'UTR (SNP) | VAF 17/26 reads (65%) | called by muse, mutect2, varscan2
- CD40 | c.*37A>G | 3'UTR (SNP) | VAF 51/112 reads (46%) | called by muse, mutect2, varscan2
- CDHR5 | c.*160_*161insCTTAAACG | 3'UTR (INS) | VAF 98/185 reads (53%) | called by mutect2, pindel
- CHML | c.*4316T>G | 3'UTR (SNP) | VAF 45/76 reads (59%) | called by muse, mutect2, varscan2
- COA1 | c.-38-1496C>G | Intron (SNP) | VAF 36/82 reads (44%) | called by muse, varscan2
- COA1 | c.-38-1556T>G | Intron (SNP) | VAF 40/80 reads (50%) | called by muse, varscan2
- CTNNA1 | c.1063-10810T>G | Intron (SNP) | VAF 16/33 reads (48%) | called by muse, mutect2, varscan2
- DICER1 | c.*406T>C | 3'UTR (SNP) | VAF 38/93 reads (41%) | called by muse, mutect2, varscan2
- EPOP | c.-143G>A | 5'UTR (SNP) | VAF 19/31 reads (61%) | called by muse, mutect2, varscan2
- ETNK1 | chr12:22625152 G>C | 5'Flank (SNP) | VAF 14/33 reads (42%) | called by muse, mutect2, varscan2
- EXTL1 | c.*174_*176del | 3'UTR (DEL) | VAF 42/88 reads (48%) | catalogued as rs1015740501; called by mutect2, pindel, varscan2
- FAM27E5 | n.517C>A | RNA (SNP) | VAF 63/129 reads (49%) | called by muse, mutect2, varscan2
- FAM76B | c.-263T>C | 5'UTR (SNP) | VAF 24/44 reads (55%) | called by muse, mutect2, varscan2
- GIPC2 | c.*2262_*2263insCT | 3'UTR (INS) | VAF 4/29 reads (14%) | catalogued as rs1465309341; called by pindel, varscan2
- IGSF3 | c.-528C>T | 5'UTR (SNP) | VAF 42/80 reads (53%) | called by muse, mutect2, varscan2
- ITGA1 | c.*472A>G | 3'UTR (SNP) | VAF 25/81 reads (31%) | called by muse, mutect2, varscan2
- ITGB1 | c.*182G>T | 3'UTR (SNP) | VAF 70/163 reads (43%) | called by muse, mutect2, varscan2
- KRTAP5-9 | c.*105C>T | 3'UTR (SNP) | VAF 90/260 reads (35%) | called by muse, mutect2
- LDLRAD3 | c.*337C>A | 3'UTR (SNP) | VAF 13/64 reads (20%) | called by muse, mutect2, varscan2
- LRAT | c.*3653C>T | 3'UTR (SNP) | VAF 33/61 reads (54%) | called by muse, mutect2, varscan2
- PGAP1 | c.*4632A>G | 3'UTR (SNP) | VAF 27/44 reads (61%) | called by muse, mutect2, varscan2
- POM121L12 | c.*85G>A | 3'UTR (SNP) | VAF 51/168 reads (30%) | called by muse, mutect2, varscan2
- PPP1CC | c.*276del | 3'UTR (DEL) | VAF 32/86 reads (37%) | catalogued as COSV100534971; called by mutect2, pindel, varscan2
- PSMA8 | c.103-4490G>C | Intron (SNP) | VAF 55/108 reads (51%) | called by muse, mutect2, varscan2
- PTPRT | c.*592G>A | 3'UTR (SNP) | VAF 46/98 reads (47%) | catalogued as rs909148029, COSV62002486; called by muse, mutect2, varscan2
- RCN1 | c.*211A>C | 3'UTR (SNP) | VAF 82/544 reads (15%) | called by muse, mutect2, varscan2
- SERPINB7 | c.*287T>C | 3'UTR (SNP) | VAF 60/117 reads (51%) | called by muse, mutect2, varscan2
- SIGLEC7 | c.1222-94C>A | Intron (SNP) | VAF 18/28 reads (64%) | called by muse, mutect2, varscan2
- SLC8A3 | c.*1610dup | 3'UTR (INS) | VAF 14/33 reads (42%) | catalogued as rs1177335454; called by mutect2, pindel, varscan2
- SPRY3 | c.*776G>T | 3'UTR (SNP) | VAF 95/204 reads (47%) | called by muse, mutect2, varscan2
- SPRY3 | c.*777A>T | 3'UTR (SNP) | VAF 92/201 reads (46%) | called by muse, mutect2, varscan2
- TLCD5 | c.*3169C>T | 3'UTR (SNP) | VAF 5/16 reads (31%) | called by muse, mutect2, varscan2
- TLK1 | c.639+88A>T | Intron (SNP) | VAF 8/14 reads (57%) | called by muse, mutect2, varscan2
- TNFRSF25 | c.*243G>A | 3'UTR (SNP) | VAF 79/217 reads (36%) | catalogued as rs1294382137, COSV61070461; called by muse, mutect2, varscan2
- TRPM6 | c.*220T>G | 3'UTR (SNP) | VAF 59/97 reads (61%) | called by muse, mutect2, varscan2
- TRPV2 | chr17:16440012 C>T | 3'Flank (SNP) | VAF 8/15 reads (53%) | called by mutect2, varscan2
- ZCCHC24 | c.*3632C>G | 3'UTR (SNP) | VAF 50/100 reads (50%) | called by muse, mutect2, varscan2
- ZDHHC11 | c.1023+1417C>T | Intron (SNP) | VAF 10/28 reads (36%) | called by muse, mutect2, varscan2
- ZNF174 | c.*379G>A | 3'UTR (SNP) | VAF 27/43 reads (63%) | called by muse, mutect2, varscan2
- ZNFX1 | chr20:49280340 G>A | 5'Flank (SNP) | VAF 30/76 reads (39%) | called by muse, mutect2, varscan2
